Somatic mutation profile of tumor specimen TCGA-EJ-5508-01A (aliquot TCGA-EJ-5508-01A-02D-1576-08) from TCGA case TCGA-EJ-5508, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.0 years (23,758 days).
Specimen TCGA-EJ-5508-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d1a677a-4624-4fed-b4f2-39d99249043f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5508-10A (Blood Derived Normal), aliquot TCGA-EJ-5508-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4acb1748-7d02-4145-8afc-a3dff260d4ac

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 15, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK2 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764008198, COSV52187322; called by muse, mutect2, varscan2
- DNM1L | c.658A>G p.M220V | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV56777766; called by muse, mutect2
- FBN3 | c.4048C>T p.R1350C | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs149551378; called by muse, mutect2, varscan2
- HTATSF1 | c.2026T>G p.S676A | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV54481160, COSV99511823; called by muse, mutect2
- HYAL3 | c.878G>T p.G293V | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.197); catalogued as COSV60188040; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 30/268 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.276); catalogued as rs201289979, COSV59828273; called by muse, mutect2, varscan2
- KCNMA1 | c.3665G>T p.R1222M (on ENST00000286628 / NM_001161352.2; = p.R1164M on NM_002247.4) | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54285619; called by muse, mutect2
- KLHL21 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1228105281, COSV66554240; called by muse, mutect2
- PLEKHG1 | c.4125A>C p.K1375N | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62050977; called by muse, mutect2, varscan2
- SAXO1 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs375442616, COSV65871918; called by muse, mutect2, varscan2
- SDF2 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 10/231 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55932389; called by muse, mutect2
- USP48 | c.1245G>T p.M415I | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57608314, COSV57614578; called by muse, mutect2
- WDR72 | c.521C>A p.S174Y | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64753745; called by muse, mutect2, varscan2
- XIRP2 | c.6962C>T p.S2321F (on ENST00000628543; = p.S2496F on NM_152381.6) | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV54732746; called by muse, mutect2
- ZNF462 | c.7043G>C p.R2348P | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV52943949, COSV52950441; called by muse, mutect2, varscan2
- ABCB4 | c.51G>A p.A17= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as COSV55941394; called by muse, mutect2, varscan2
- APOBEC2 | c.480G>A p.P160= | Silent (SNP) | VAF 36/187 reads (19%) | catalogued as rs140342245, COSV55143595; called by muse, varscan2
- FOLR3 | c.342G>T p.G114= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV61530893; called by mutect2, varscan2
- N6AMT1 | c.195T>C p.S65= | Silent (SNP) | VAF 27/180 reads (15%) | catalogued as COSV58135750, COSV58135895; called by muse, mutect2, varscan2
- PLA2G4A | c.1074A>G p.K358= | Silent (SNP) | VAF 28/179 reads (16%) | catalogued as COSV66556802; called by muse, mutect2, varscan2
- RALGAPA1 | c.5925A>C p.T1975= | Silent (SNP) | VAF 6/95 reads (6%) | catalogued as COSV51896074; called by muse, mutect2
